Somatic mutation profile of tumor specimen TCGA-CR-7367-01A (aliquot TCGA-CR-7367-01A-11D-2012-08) from TCGA case TCGA-CR-7367, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 52.3 years (19,116 days).
Specimen TCGA-CR-7367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a40b8812-a57b-43b4-843f-f3a1fcfa2aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7367-10A (Blood Derived Normal), aliquot TCGA-CR-7367-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/492d021c-cfb6-4b26-bf84-49910cb3eb70

The open-access MAF lists 186 somatic variants for this specimen: 142 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 40, Nonsense Mutation 11, Frame Shift Ins 3, Splice Site 2, RNA 2, Intron 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRAXAS1 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV99788526; called by muse, mutect2, varscan2
- ACAD10 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100564298; called by muse, mutect2, varscan2
- ACBD5 | c.1577A>G p.Y526C (on ENST00000375888 / NM_001352568.1; = p.Y517C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV65518805; called by muse, mutect2, varscan2
- ACTN4 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99400378; called by muse, mutect2, varscan2
- ADH1A | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.244); catalogued as COSV99265819; called by muse, mutect2, varscan2
- ADH4 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99644235; called by muse, mutect2
- AKAP4 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.212); catalogued as COSV100654293; called by muse, mutect2, varscan2
- AKT3 | c.1207A>G p.S403G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99795730; called by muse, mutect2, varscan2
- AMY2B | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs764180848, COSV63713836; called by muse, mutect2, varscan2
- ANKRD55 | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.219); catalogued as COSV100591436; called by muse, mutect2, varscan2
- ANO2 | c.2603A>G p.D868G (on ENST00000356134 / NM_001278597.3; = p.D872G on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100501293; called by muse, mutect2, varscan2
- ANO3 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); catalogued as COSV99883463; called by muse, mutect2, varscan2
- APOB | c.3286A>G p.I1096V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99266143; called by muse, mutect2, varscan2
- ARSG | c.1090A>T p.S364C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101477902; called by muse, mutect2
- ARSI | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV60818675; called by muse, mutect2, varscan2
- ASAH2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs761627134, COSV61482768; called by muse, mutect2, varscan2
- ASIC2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.322); catalogued as rs779793341, COSV63323976; called by muse, mutect2, varscan2
- ASTE1 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99393865; called by muse, mutect2, varscan2
- ATAD2B | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99477876; called by muse, mutect2, varscan2
- ATN1 | c.3047C>A p.S1016Y | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100755828; called by muse, mutect2, varscan2
- ATRIP | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100202673, COSV100202801; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3538C>T p.H1180Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV100863804; called by muse, mutect2, varscan2
- C8A | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100776532; called by muse, mutect2, varscan2
- CAPN15 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1487254124, COSV99562521; called by muse, mutect2, varscan2
- CAPRIN2 | c.1958C>A p.P653Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV51831710, COSV99195532; called by mutect2, varscan2
- CCDC54 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53758095, COSV53758684, COSV99660233; called by muse, mutect2, varscan2
- CD69 | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV99946122; called by muse, mutect2, varscan2
- CDH7 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542594, COSV59888359; called by muse, mutect2, varscan2
- CDK8 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as COSV101037342; called by muse, mutect2, varscan2
- CFAP54 | c.4826T>C p.V1609A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100733241; called by muse, mutect2, varscan2
- CHRND | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs140455307, COSV99286049; called by muse, mutect2, varscan2
- CMA1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs755977857, COSV51625626; called by muse, mutect2, varscan2
- CNTROB | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1481588383, COSV66608115; called by muse, mutect2
- COL11A1 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as rs1448065580, COSV100617044, COSV62178528; called by muse, mutect2, varscan2
- COL1A1 | c.4252C>T p.H1418Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56803792, COSV99867452, COSV99868099; called by muse, mutect2, varscan2
- COL24A1 | c.1724C>G p.P575R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as COSV100993507; called by muse, mutect2, varscan2
- CPS1 | c.2710C>G p.L904V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV51817296, COSV99243264; called by mutect2, varscan2
- CSMD3 | c.10931T>C p.F3644S (on ENST00000297405 / NM_001363185.1; = p.F3475S on NM_052900.3) | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV52198784; called by muse, mutect2, varscan2
- DAB1 | c.92T>C p.L31S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100140250; called by muse, mutect2, varscan2
- DGKH | c.3619G>A p.G1207R (on ENST00000337343 / NM_178009.5; = p.G1163E on NM_152910.6) | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99818999; called by muse, mutect2, varscan2
- DOC2A | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs772945741, COSV58751866; called by mutect2, varscan2
- DQX1 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs201394061, COSV52045613, COSV99283684; called by muse, mutect2, varscan2
- EDNRB | c.808A>G p.I270V (on ENST00000377211 / NM_001201397.1; = p.I180V on NM_000115.5) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100526761; called by muse, mutect2, varscan2
- ELAVL4 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63914820; called by muse, mutect2, varscan2
- ELP6 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99948170; called by muse, mutect2, varscan2
- EPRS1 | c.3673A>G p.I1225V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100859408; called by muse, mutect2
- ESYT1 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as rs1319448461, COSV99920042; called by muse, mutect2, varscan2
- EXOC4 | c.1211A>T p.K404I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99554323; called by muse, mutect2
- FAM131A | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.022); catalogued as rs1304520956, COSV99658675; called by muse, mutect2, varscan2
- FAM155A | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101028656; called by muse, mutect2, varscan2
- FCRL6 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs146779081; called by muse, mutect2
- FUT9 | c.341G>C p.S114T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs376403164, COSV100133789; called by muse, mutect2, varscan2
- GNG11 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99949370; called by muse, mutect2, varscan2
- GNPAT | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV100791644; called by muse, mutect2, varscan2
- GRM3 | c.908G>A p.W303* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100862620; called by muse, mutect2, varscan2
- GTF3C1 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.967); catalogued as COSV100649497; called by muse, mutect2, varscan2
- H3C11 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV100137951; called by muse, mutect2, varscan2
- H4C6 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100897498; called by muse, mutect2, varscan2
- HDAC4 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.946); catalogued as rs1175330507, COSV61874300; called by muse, mutect2, varscan2
- HERC6 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV99910581; called by muse, mutect2
- IRF2BP1 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100138916; called by muse, mutect2, varscan2
- ITGB7 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs779111282, COSV99914126; called by muse, mutect2, varscan2
- ITPR3 | c.5804G>A p.G1935D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100967522; called by muse, mutect2, varscan2
- KDM5C | c.1403_1404insT p.E468Dfs*49 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as COSV100949276; called by mutect2, pindel, varscan2
- KLHL23 | c.1187G>T p.W396L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55866491; called by muse, mutect2, varscan2
- LAMA5 | c.8636G>A p.G2879E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99440555; called by muse, mutect2, varscan2
- LEF1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251819558, COSV99489702; called by muse, mutect2, varscan2
- LRP1 | c.12800G>A p.C4267Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99676218; called by muse, mutect2, varscan2
- LRRC56 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV99530291, COSV99530299; called by muse, mutect2, varscan2
- MAPK10 | c.825C>G p.F275L (on ENST00000359221 / NM_001351625.2; = p.F313L on NM_002753.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV100174694; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MGMT | c.621G>T p.L207F (on ENST00000306010; = p.L176F on NM_002412.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100023428; called by muse, mutect2, varscan2
- MKI67 | c.758A>C p.Q253P | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100896669; called by muse, mutect2
- MTX3 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1400961934, COSV101560497; called by muse, mutect2, varscan2
- MYADM | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV100425102; called by muse, mutect2, varscan2
- MYT1L | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67711894; called by muse, mutect2, varscan2
- N4BP1 | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99285271; called by muse, mutect2, varscan2
- NBAS | c.5165G>C p.R1722T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99870269; called by muse, varscan2
- NLRP2 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99672363; called by muse, mutect2, varscan2
- NLRP2 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV54754117, COSV99672365; called by muse, mutect2, varscan2
- NLRP4 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs1227029230, COSV100016514; called by muse, mutect2, varscan2
- NSD2 | c.2144A>T p.H715L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100373488; called by muse, mutect2, varscan2
- NUMA1 | c.707A>T p.E236V | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100706279; called by muse, mutect2, varscan2
- OR2L3 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 32/159 reads (20%) | catalogued as COSV100741989, COSV63454825; called by muse, mutect2, varscan2
- OR51V1 | c.423T>G p.N141K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100343404; called by muse, mutect2, varscan2
- OR6X1 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100020572; called by muse, mutect2, varscan2
- PCDHA1 | c.98A>C p.Y33S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100974381; called by muse, mutect2, varscan2
- PCDHA3 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV100793511; called by muse, mutect2
- PCDHA6 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV65344585, COSV65344600; called by muse, mutect2, varscan2
- PCDHAC2 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99150270; called by muse, mutect2, varscan2
- PCDHB10 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); catalogued as COSV99504500; called by muse, mutect2, varscan2
- PDE4A | c.1225C>T p.R409C (on ENST00000380702 / NM_001111307.2; = p.R170C on NM_006202.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs201196140, COSV53351248; called by muse, mutect2, varscan2
- PIAS3 | c.1135A>G p.I379V | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs782673556, COSV100566807; called by muse, mutect2, varscan2
- PIWIL4 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.383); catalogued as COSV100133270; called by muse, mutect2, varscan2
- POM121L12 | c.749A>T p.D250V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV101374933; called by muse, mutect2, varscan2
- PXDNL | c.3766G>T p.V1256L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV100684315; called by muse, mutect2, varscan2
- RAF1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.063); catalogued as rs896491732, COSV99312059, COSV99312792; called by muse, mutect2, varscan2
- RNF123 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772954203, COSV100570855, COSV59687436; called by muse, mutect2, varscan2
- SALL3 | c.3675G>A p.M1225I | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101610016; called by muse, mutect2, varscan2
- SCFD2 | c.1931A>G p.D644G | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101189390; called by muse, mutect2, varscan2
- SETD1A | c.4910A>C p.K1637T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353204; called by muse, mutect2, varscan2
- SETD6 | c.1109C>T p.T370I (on ENST00000219315 / NM_001160305.4; = p.T346I on NM_024860.3) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); catalogued as rs1367935818, COSV99262216; called by muse, mutect2, varscan2
- SIM1 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1315267889, COSV53490880; called by muse, mutect2
- SLC26A7 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs781221719, COSV99403638; called by muse, mutect2, varscan2
- SLC35G2 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101262041; called by muse, mutect2, varscan2
- SLC46A2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs140881150; called by muse, mutect2, varscan2
- SLC4A4 | c.2806C>T p.Q936* (on ENST00000264485 / NM_001098484.3; = p.Q892* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99140481; called by muse, mutect2, varscan2
- SLITRK1 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100999876, COSV65674503; called by muse, mutect2, varscan2
- SMURF2 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1353684331, COSV99300807; called by muse, mutect2
- ST8SIA5 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV100164749; called by muse, mutect2, varscan2
- SYNE2 | c.6803T>C p.F2268S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV100647934; called by muse, mutect2
- SYT4 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99673960; called by muse, mutect2, varscan2
- TBXAS1 | c.1241C>A p.A414E | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV99695512; called by muse, mutect2
- TFB1M | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99265618; called by muse, mutect2
- THEM5 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1320084272, COSV64312822; called by muse, varscan2
- THSD7A | c.3053G>T p.C1018F | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV101448768; called by muse, mutect2, varscan2
- TLN2 | c.84C>G p.Y28* | Nonsense Mutation (SNP) | VAF 20/151 reads (13%) | catalogued as COSV100169294; called by muse, mutect2, varscan2
- TSHZ1 | c.2552T>A p.L851Q (on ENST00000580243 / NM_001308210.2; = p.L806Q on NM_005786.6) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.873); catalogued as COSV100433765; called by muse, mutect2, varscan2
- TSKS | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55876573; called by mutect2, varscan2
- TXNDC11 | c.1016C>T p.T339I (on ENST00000356957 / NM_001303447.2; = p.T312I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99297895; called by muse, mutect2, varscan2
- UCK1 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64736507, COSV64736549; called by muse, mutect2, varscan2
- UGT2B4 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV100522473; called by muse, mutect2, varscan2
- UNC5B | c.2603A>G p.N868S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100100867; called by muse, mutect2, varscan2
- UROC1 | c.965+1G>A p.X322_splice | Splice Site (SNP) | VAF 36/369 reads (10%) | catalogued as COSV99331638; called by muse, mutect2
- VPS13D | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs772428099, COSV100693205; called by muse, mutect2, varscan2
- VSIG10 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs1421908727, COSV100821300; called by muse, mutect2
- WDR5 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 20/204 reads (10%) | catalogued as COSV100681930; called by muse, mutect2
- WRN | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as rs1428459485, COSV99989233; called by muse, mutect2, varscan2
- ZFP64 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs764218342, COSV53804352; called by muse, mutect2, varscan2
- ZNF117 | c.1096T>A p.C366S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99275784; called by muse, mutect2, varscan2
- ZNF318 | c.6762G>A p.M2254I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs749324573, COSV100546301; called by muse, mutect2, varscan2
- ZNF581 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1568539112, COSV54401674; called by muse, mutect2, varscan2
- ZNF888 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101480809; called by muse, varscan2
- ZNF99 | c.1903A>G p.T635A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs202061112; called by muse, mutect2, varscan2
- B3GAT3 | c.188dup p.A64Cfs*7 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- GDF2 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- HNRNPR | c.1608_1613del p.G537_P538del | In Frame Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- SLFN5 | c.2406dup p.Y803Ifs*2 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- STT3A | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D14 | c.1866_1876del p.L623Rfs*104 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- USP8 | c.1804-26_1818del p.X602_splice | Splice Site (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel
- ACSM2A | c.945C>T p.Y315= (on ENST00000219054; = p.Y236= on NM_001308169.2) | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV99525359; called by muse, mutect2, varscan2
- ADAMTS20 | c.3930C>T p.T1310= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as rs375296101, COSV101166301; called by muse, mutect2
- ALS2 | c.2661G>A p.K887= | Silent (SNP) | VAF 138/223 reads (62%) | catalogued as COSV51892465; called by muse, mutect2, varscan2
- ARHGAP6 | c.918A>G p.K306= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100273089; called by muse, mutect2, varscan2
- ASTN2 | c.678G>T p.A226= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100524954, COSV100528320; called by muse, mutect2, varscan2
- ATP6V0C | c.285C>T p.A95= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs761344058, COSV99565926; called by muse, mutect2, varscan2
- ATP8B3 | c.3237C>T p.F1079= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs746281643, COSV100034525; called by mutect2, varscan2
- CBLB | c.1860A>T p.T620= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV99913624; called by muse, mutect2, varscan2
- CDH6 | c.1983C>T p.D661= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs766877667, COSV99419568; called by muse, mutect2, varscan2
- CGB5 | c.285C>T p.G95= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1327851993; called by mutect2, varscan2
- CHD6 | c.156T>C p.A52= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV100498386; called by muse, mutect2, varscan2
- CLN5 | c.30C>T p.G10= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs756651200, COSV101080341; called by muse, mutect2, varscan2
- COL25A1 | c.189C>T p.I63= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV67650580; called by muse, mutect2, varscan2
- DHX37 | c.228G>A p.E76= | Silent (SNP) | VAF 84/207 reads (41%) | catalogued as COSV100439300; called by muse, mutect2, varscan2
- DST | c.3570C>A p.L1190= (on ENST00000361203 / NM_001374722.1; = p.L864= on NM_001723.6) | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99757384; called by muse, mutect2, varscan2
- GYPC | c.141C>A p.G47= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99391837; called by muse, mutect2
- H2BW1 | c.144A>G p.K48= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99475087; called by muse, mutect2, varscan2
- KIAA1549 | c.3775C>T p.L1259= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV54327918, COSV99651050; called by muse, mutect2, varscan2
- LEXM | c.1062T>A p.G354= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100827647; called by muse, mutect2, varscan2
- LRRC58 | c.649C>T p.L217= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MCCC2 | c.465G>A p.R155= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs184731247, COSV100040349; called by muse, mutect2, varscan2
- NACC2 | c.873C>T p.S291= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1051314989; called by muse, mutect2, varscan2
- OR2L3 | c.198C>G p.S66= | Silent (SNP) | VAF 40/393 reads (10%) | catalogued as COSV100741991, COSV63455014; called by muse, mutect2, varscan2
- OSMR | c.2793T>C p.S931= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as rs770623797, COSV99953279; called by muse, mutect2, varscan2
- PARP12 | c.2028G>A p.Q676= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99694110; called by muse, mutect2, varscan2
- PDXDC1 | c.1800G>A p.E600= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV99816967; called by muse, mutect2, varscan2
- PXDNL | c.3765G>T p.R1255= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV62502842; called by mutect2, varscan2
- RPS6KB1 | c.663G>A p.P221= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1485684537, COSV56678428; called by muse, mutect2, varscan2
- RYR2 | c.2007G>A p.Q669= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100771083; called by muse, mutect2, varscan2
- SNAP47 | c.381C>T p.S127= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV100248257; called by muse, mutect2
- SNRPB2 | c.642G>A p.P214= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs767397601, COSV55718911; called by muse, mutect2, varscan2
- TAS1R1 | c.951C>T p.R317= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs753410366, COSV100039717; called by muse, mutect2, varscan2
- TMBIM4 | c.630C>T p.Y210= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs554625377, COSV99660358; called by muse, mutect2, varscan2
- TNKS1BP1 | c.795T>C p.A265= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1323037368, COSV100836102; called by muse, mutect2, varscan2
- TRPV5 | c.1168C>T p.L390= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99520636; called by muse, mutect2
- VNN3 | c.354C>T p.N118= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV99258385; called by muse, mutect2, varscan2
- VPS41 | c.2520T>G p.A840= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100053989; called by muse, mutect2, varscan2
- WNT8A | c.645G>A p.A215= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs776674977, COSV100843059; called by muse, mutect2, varscan2
- ZG16B | c.240T>G p.S80= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV101206762; called by muse, mutect2, varscan2
- ZNF625 | c.342G>A p.R114= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100863515; called by muse, mutect2, varscan2
- CDC14B | c.161-1313G>A | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99685820; called by muse, mutect2, varscan2
- DCHS2 | n.6281C>T | RNA (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100601948; called by muse, mutect2, varscan2
- GH2 | c.457-65G>A | Intron (SNP) | VAF 14/101 reads (14%) | catalogued as rs397839840, COSV100236999; called by muse, mutect2, varscan2
- MIR891A | n.20C>A | RNA (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
